Somatic mutation profile of tumor specimen TCGA-HU-A4GP-01A (aliquot TCGA-HU-A4GP-01A-11D-A25D-08) from TCGA case TCGA-HU-A4GP, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 62.2 years (22,711 days).
Specimen TCGA-HU-A4GP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a783b48-c064-4545-8a7d-e75f508ce506.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4GP-10A (Blood Derived Normal), aliquot TCGA-HU-A4GP-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3644d71-df44-45ed-9500-b7ff80a4626e

The open-access MAF lists 201 somatic variants for this specimen: 143 protein-altering or splice-affecting, 55 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 55, Nonsense Mutation 5, Frame Shift Ins 4, Frame Shift Del 4, Intron 1, Splice Site 1, 5'Flank 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1622G>A p.R541Q (on ENST00000404938 / NM_001163941.2; = p.R96Q on NM_178559.6) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776819013, COSV51718331; called by muse, mutect2, varscan2
- ACAP3 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.156); catalogued as COSV61223191; called by muse, mutect2, varscan2
- ACTR3 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV54302653; called by muse, mutect2, varscan2
- ADCY8 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53897594; called by muse, mutect2
- ADORA1 | c.808A>C p.T270P | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV55143861; called by muse, mutect2, varscan2
- AGPAT3 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99377519; called by muse, mutect2
- ANKK1 | c.1727G>T p.C576F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.29); catalogued as COSV58273829; called by muse, varscan2
- ARHGAP32 | c.4933C>T p.R1645W (on ENST00000310343 / NM_001378025.1; = p.R1296W on NM_014715.4) | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59854196; called by muse, mutect2
- ARHGAP33 | c.1760G>C p.G587A | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.078); catalogued as COSV50148027; called by muse, mutect2, varscan2
- ATG10 | c.408T>A p.Y136* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV56431129; called by muse, mutect2, varscan2
- ATP1B1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754593629, COSV63179937; called by muse, mutect2, varscan2
- CACNA1H | c.6463C>T p.R2155W | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1490888804, COSV52357414; called by muse, mutect2, varscan2
- CACNG3 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV50070992; called by muse, mutect2, varscan2
- CAMK2B | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs774834635, COSV51665042; called by muse, mutect2, varscan2
- CAPRIN2 | c.2459G>C p.R820T | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51834848; called by muse, mutect2, varscan2
- CASP4 | c.8-1G>A p.X3_splice | Splice Site (SNP) | VAF 9/80 reads (11%) | catalogued as rs200174319, COSV67744775; called by muse, mutect2, varscan2
- CCDC85A | c.620T>A p.V207E | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV68154749; called by muse, mutect2, varscan2
- CCZ1 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV58075196; called by muse, mutect2, varscan2
- CD163L1 | c.2270C>A p.S757Y | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (1); PolyPhen probably damaging (0.972); catalogued as COSV58022993; called by muse, mutect2, varscan2
- CD5L | c.959A>T p.Q320L | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV63822872; called by muse, mutect2, varscan2
- CHST1 | c.842A>C p.N281T | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV57325192, COSV57325694; called by muse, mutect2
- CNTN3 | c.2431G>T p.A811S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV55181727, COSV99724420; called by muse, mutect2
- COL11A1 | c.1594G>T p.G532C | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100616848, COSV62174716, COSV62185632; called by muse, mutect2
- COL12A1 | c.8995C>A p.L2999M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.319); catalogued as COSV100486072; called by muse, mutect2, varscan2
- COL6A3 | c.2336G>T p.S779I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV55104546; called by muse, mutect2, varscan2
- COLEC11 | c.578T>A p.L193Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52596677; called by muse, mutect2
- CSMD3 | c.1593A>C p.E531D (on ENST00000297405 / NM_001363185.1; = p.E427D on NM_052900.3) | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV52105113, COSV52338075; called by muse, mutect2
- CYP11B1 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as COSV52829751; called by muse, mutect2, varscan2
- DIXDC1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1472099566, COSV67742227; called by muse, mutect2, varscan2
- DKK1 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV64760651; called by muse, mutect2
- DMBT1 | c.6080G>A p.R2027H (on ENST00000338354 / NM_001377530.1; = p.R1270H on NM_004406.3) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768251433, COSV57557328; called by muse, mutect2, varscan2
- DMXL2 | c.5534G>A p.R1845Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1429598525, COSV51844369; called by muse, mutect2, varscan2
- ELF2 | c.248C>T p.S83L (on ENST00000379550 / NM_001331036.2; = p.S23L on NM_006874.4) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV55494073, COSV55495122; called by muse, mutect2, varscan2
- ELMO1 | c.1490G>C p.S497T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs956711929, COSV60319976; called by muse, mutect2, varscan2
- ERCC3 | c.1237C>A p.L413M | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV53429268; called by muse, mutect2, varscan2
- EXOSC1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1206481822, COSV100602426; called by muse, mutect2
- FAT1 | c.6648C>A p.Y2216* | Nonsense Mutation (SNP) | VAF 40/106 reads (38%) | catalogued as COSV71675570; called by muse, mutect2, varscan2
- FERD3L | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51764002, COSV99285069; called by muse, mutect2
- FOXI2 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV59094876; called by muse, mutect2, varscan2
- GABRB1 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as rs1490601406, COSV54996108; called by muse, mutect2
- GFI1 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54043697; called by muse, mutect2, varscan2
- GLI3 | c.2120C>G p.P707R | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101229900; called by muse, mutect2, varscan2
- GPD1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs774260508, COSV56548941; called by muse, mutect2, varscan2
- GPRASP1 | c.3275G>A p.S1092N | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV64356291; called by muse, mutect2
- GPSM3 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV66683106; called by muse, mutect2, varscan2
- GRIA1 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs369322935; called by muse, mutect2, varscan2
- GRM2 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV56586872; called by muse, mutect2, varscan2
- GRM7 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1559306156, COSV63159229, COSV63162440; called by muse, mutect2, varscan2
- H2BC4 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100019927; called by muse, mutect2
- HAUS2 | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); catalogued as COSV53000964; called by muse, mutect2
- INSR | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV57170998; called by muse, mutect2, varscan2
- INTS6L | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 70/119 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV66085800; called by muse, mutect2, varscan2
- IRS4 | c.3689A>T p.D1230V | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV64535528; called by muse, mutect2
- IRS4 | c.1207A>T p.S403C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV64535535; called by muse, mutect2
- ITPR2 | c.830G>T p.S277I | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67274858; called by muse, mutect2, varscan2
- KCNJ8 | c.630C>A p.F210L | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV53717919; called by muse, mutect2, varscan2
- KCNMB2 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.039); catalogued as rs1335861573, COSV64201891; called by muse, mutect2, varscan2
- KDM5C | c.2007G>C p.E669D | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.566); catalogued as COSV100949234; called by muse, mutect2
- KIF14 | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV104426722, COSV66263534; called by muse, mutect2, varscan2
- KIFC1 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779218729, COSV65729707; called by muse, mutect2, varscan2
- KLHL41 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52931357; called by muse, mutect2
- KMT2C | c.14552G>A p.C4851Y | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51488343; called by muse, mutect2
- KPNB1 | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99268168; called by muse, mutect2
- LEPR | c.2465C>A p.P822Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60762253; called by muse, mutect2
- LYST | c.966G>T p.L322F | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV67712283; called by muse, mutect2
- MAB21L1 | c.433T>A p.Y145N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV59814784; called by muse, mutect2, varscan2
- MAP3K13 | c.2446T>A p.S816T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV53995336; called by muse, mutect2, varscan2
- MCF2 | c.977A>T p.K326I | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV58492833; called by muse, mutect2, varscan2
- MSLNL | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs530397353, COSV53504342; called by muse, mutect2, varscan2
- MUC4 | c.13721G>C p.W4574S (on ENST00000463781 / NM_018406.7; = p.W338S on NM_004532.6) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57799214; called by muse, mutect2, varscan2
- NAT16 | c.343G>C p.A115P | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55865490; called by muse, mutect2, varscan2
- NKX2-1 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs1433487495, COSV61387918; called by muse, mutect2, varscan2
- NRXN3 | c.725C>T p.A242V (on ENST00000557594 / NM_001272020.2; = p.A874V on NM_004796.6) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs760098836, COSV55322573; called by muse, mutect2, varscan2
- NTM | c.528G>A p.A176= | Splice Region (SNP) | VAF 21/42 reads (50%) | catalogued as rs183795743, COSV66177690; called by muse, mutect2, varscan2
- OBSCN | c.3361G>T p.G1121C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV52815606; called by muse, mutect2, varscan2
- OR10Q1 | c.931A>T p.I311F | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57471609; called by muse, mutect2, varscan2
- OR12D2 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65829805; called by muse, varscan2
- OR51S1 | c.320T>A p.L107Q | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV59059759; called by muse, mutect2
- OR52E4 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100389264, COSV57625603; called by muse, mutect2
- OR5D14 | c.212T>G p.V71G | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV59458086; called by muse, mutect2, varscan2
- OR6M1 | c.745C>A p.H249N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV58434589; called by muse, mutect2, varscan2
- OR8K3 | c.860T>C p.L287S | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV57130882, COSV57132564, COSV57133424; called by muse, mutect2, varscan2
- ORC3 | c.2123G>A p.W708* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as rs998630524, COSV57642887; called by muse, mutect2, varscan2
- PCDHA11 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.524); catalogued as COSV56475988; called by muse, mutect2, varscan2
- PCDHGA1 | c.1642C>A p.L548I | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.361); catalogued as COSV100965997; called by muse, mutect2
- PCLO | c.2166G>T p.Q722H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV61659379; called by muse, mutect2, varscan2
- PCLO | c.1760C>G p.T587S | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.048); catalogued as COSV61659388; called by muse, mutect2
- PEG3 | c.2964G>T p.Q988H | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55644206; called by muse, mutect2, varscan2
- PNLIPRP3 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV65048474, COSV65049414; called by muse, mutect2, varscan2
- PRAMEF15 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 106/500 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1236831573; called by muse, mutect2, varscan2
- PTCH1 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 5/127 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV100108812; called by muse, mutect2
- PTCH1 | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 5/126 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV100108820; called by muse, mutect2
- PTPRC | c.1610G>T p.C537F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100722720; called by muse, mutect2
- PTPRT | c.1160T>G p.V387G | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV100624218, COSV62010963; called by muse, mutect2
- RAB22A | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV54831402, COSV54833419, COSV99720456; called by muse, mutect2, varscan2
- RBM46 | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55981340; called by muse, mutect2, varscan2
- RBP3 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs782631087; called by muse, mutect2, varscan2
- RIMS2 | c.1225T>C p.S409P (on ENST00000666250 / NM_001348490.2; = p.S217P on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV51714784; called by muse, mutect2, varscan2
- RREB1 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58563460; called by muse, mutect2, varscan2
- SCGB1D2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.8); catalogued as rs775701487, COSV55274267; called by muse, mutect2, varscan2
- SDK1 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs200916324, COSV67379142; called by muse, mutect2, varscan2
- SEC16A | c.4333T>A p.F1445I | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51521556; called by muse, mutect2, varscan2
- SEMA3D | c.504A>G p.I168M | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99406755; called by muse, mutect2
- SERF2 | c.64G>C p.V22L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV51050942; called by muse, mutect2, varscan2
- SERPINA10 | c.821A>C p.K274T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.665); catalogued as rs748068345, COSV56229376; called by muse, mutect2, varscan2
- SF3B1 | c.3044A>G p.D1015G | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59223856; called by muse, mutect2
- SH3TC2 | c.1077G>T p.E359D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60466936, COSV60468682; called by muse, mutect2, varscan2
- SLC12A5 | c.622T>A p.Y208N (on ENST00000454036 / NM_001134771.2; = p.Y185N on NM_020708.5) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54800134; called by muse, mutect2, varscan2
- SLFN11 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs760685634, COSV57700102; called by muse, mutect2, varscan2
- TEX14 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53624393; called by muse, mutect2, varscan2
- TEX47 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV51879835; called by muse, mutect2, varscan2
- TG | c.4192C>T p.R1398C | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as rs140482581, COSV55086797; called by muse, mutect2, varscan2
- TG | c.7132C>T p.R2378W | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs778035632, COSV55090578; called by muse, mutect2, varscan2
- TLR9 | c.499C>A p.H167N | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as COSV59727334; called by muse, mutect2, varscan2
- TMEM139 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as rs371498733; called by muse, mutect2
- TRA2A | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1272291525, COSV51718559; called by muse, mutect2, varscan2
- TRHDE | c.1338G>T p.W446C | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53861292; called by muse, mutect2
- TRIM36 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV56692682; called by muse, mutect2, varscan2
- TTC37 | c.1803G>T p.W601C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62456438; called by muse, mutect2
- UBQLNL | c.586T>C p.S196P | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV66494315; called by muse, mutect2, varscan2
- USP20 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV59617891; called by muse, mutect2
- UTRN | c.9305G>A p.R3102Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776348759, COSV62304919; called by muse, mutect2, varscan2
- VCAN | c.7115G>T p.S2372I | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.459); catalogued as COSV54114254; called by muse, mutect2, varscan2
- VCAN | c.8597A>T p.K2866M | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV54114264; called by muse, mutect2
- WDR6 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV58247012; called by muse, varscan2
- XAF1 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs894389758, COSV60972972; called by muse, mutect2, varscan2
- XIRP2 | c.5636A>C p.N1879T (on ENST00000628543; = p.N2054T on NM_152381.6) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.946); catalogued as COSV54727731; called by muse, mutect2, varscan2
- ZFHX4 | c.7062T>A p.D2354E | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV51489266; called by muse, mutect2, varscan2
- ZIC1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51553293; called by muse, mutect2, varscan2
- ZMYM1 | c.283dup p.I95Nfs*26 | Frame Shift Ins (INS) | VAF 55/147 reads (37%) | catalogued as rs1557672994; called by mutect2, varscan2
- ZNF57 | c.1419G>C p.E473D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as COSV60984464; called by muse, mutect2, varscan2
- ZNF570 | c.1205C>A p.A402D | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.802); catalogued as COSV57580439; called by muse, mutect2, varscan2
- ZNF675 | c.1373G>A p.G458D | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs150723446; called by muse, mutect2, varscan2
- DAPK1 | c.2604del p.E868Dfs*3 | Frame Shift Del (DEL) | VAF 30/72 reads (42%) | called by mutect2, pindel
- GPATCH8 | c.823_824del p.A275Sfs*13 | Frame Shift Del (DEL) | VAF 46/155 reads (30%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.461dup p.I155Dfs*9 | Frame Shift Ins (INS) | VAF 38/181 reads (21%) | called by mutect2, pindel, varscan2
- MAGI2 | c.3097del p.L1033Wfs*41 | Frame Shift Del (DEL) | VAF 60/200 reads (30%) | called by mutect2, pindel, varscan2
- MYO9A | c.4561_4562del p.D1521Yfs*13 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- PLD1 | c.1571G>T p.R524I | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2
- RRBP1 | c.2077_2080dup p.P694Rfs*157 (on ENST00000377813 / NM_001365613.2; = p.P261Rfs*157 on NM_004587.3) | Frame Shift Ins (INS) | VAF 28/136 reads (21%) | called by mutect2, pindel, varscan2
- SCN3A | c.1653dup p.F552Ifs*22 | Frame Shift Ins (INS) | VAF 32/131 reads (24%) | called by mutect2, pindel, varscan2
- TPTE | c.740T>G p.I247S (on ENST00000618007 / NM_199261.4; = p.I229S on NM_199259.4) | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ABCC5 | c.3591C>T p.N1197= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs377172194, COSV55595263; called by muse, mutect2, varscan2
- ADCY8 | c.345C>T p.S115= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs972171053, COSV53922804; called by muse, mutect2
- AGRN | c.1587G>A p.A529= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs200506573, COSV101038732, COSV65071872; called by muse, mutect2, varscan2
- ARHGAP35 | c.126C>T p.F42= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as rs772729752, COSV68334760; called by muse, mutect2
- ATRNL1 | c.2836T>C p.L946= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV58109744; called by muse, mutect2, varscan2
- BMPER | c.1767T>C p.C589= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV51828941; called by muse, mutect2
- CDAN1 | c.3210G>T p.L1070= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV62333736; called by muse, mutect2, varscan2
- CDH15 | c.825A>G p.G275= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV57026668; called by muse, mutect2, varscan2
- COL11A1 | c.2436T>G p.P812= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100616846, COSV62183725; called by muse, mutect2
- COL6A2 | c.2904C>T p.N968= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs143569686; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DNAH8 | c.10629A>G p.K3543= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV100547476, COSV59473422; called by muse, mutect2, varscan2
- EARS2 | c.912C>T p.P304= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs753022070, COSV101492149, COSV71942864; ClinVar: likely benign; called by muse, mutect2, varscan2
- ELAVL4 | c.372G>A p.P124= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as rs528644967, COSV63916163; called by muse, mutect2, varscan2
- EPHB1 | c.474A>T p.V158= | Silent (SNP) | VAF 19/224 reads (8%) | catalogued as COSV101213224; called by muse, mutect2
- FAM83F | c.1140G>A p.T380= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs551543842, COSV61001047; called by muse, mutect2, varscan2
- FAT4 | c.342G>A p.A114= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV67897085; called by muse, mutect2, varscan2
- FSTL5 | c.2322G>T p.G774= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV60222020; called by muse, mutect2, varscan2
- FZD2 | c.1197C>T p.S399= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as COSV59529401; called by muse, mutect2, varscan2
- GABRA1 | c.1104C>T p.Y368= | Silent (SNP) | VAF 47/107 reads (44%) | catalogued as rs771832995, COSV50099123, COSV99196334; ClinVar: likely benign; called by muse, mutect2, varscan2
- GBP1 | c.780C>A p.P260= | Silent (SNP) | VAF 26/258 reads (10%) | catalogued as COSV65084311; called by muse, mutect2
- HTT | c.9207C>T p.V3069= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs745832191, COSV61861620; called by muse, mutect2, varscan2
- IFNB1 | c.225C>T p.D75= | Silent (SNP) | VAF 62/141 reads (44%) | catalogued as rs368199428; called by muse, mutect2, varscan2
- IL6R | c.1260C>T p.P420= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs1264270707, COSV59818696; called by muse, mutect2, varscan2
- LCE3A | c.168G>A p.R56= | Silent (SNP) | VAF 50/103 reads (49%) | catalogued as rs758179270, COSV100175103, COSV59551038; called by muse, mutect2, varscan2
- LUZP2 | c.57C>T p.S19= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV61215782; called by muse, mutect2, varscan2
- MARK1 | c.2238C>T p.D746= | Silent (SNP) | VAF 52/78 reads (67%) | catalogued as rs141632214; called by muse, mutect2, varscan2
- MISP | c.1203G>A p.P401= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs769053768, COSV53121902; called by muse, mutect2
- MTMR4 | c.147C>T p.A49= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs764037968, COSV60202796; called by muse, mutect2, varscan2
- MUC16 | c.15729G>A p.V5243= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV67486961, COSV67503154; called by muse, mutect2, varscan2
- OR4C11 | c.195C>G p.S65= | Silent (SNP) | VAF 35/50 reads (70%) | catalogued as COSV56354691; called by muse, mutect2, varscan2
- OR8K3 | c.510C>A p.G170= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV57132554; called by muse, mutect2
- PCDHA11 | c.1230C>T p.S410= | Silent (SNP) | VAF 71/116 reads (61%) | catalogued as rs564033882, COSV56532888; called by muse, mutect2, varscan2
- PCDHGA2 | c.1884G>A p.T628= | Silent (SNP) | VAF 63/144 reads (44%) | catalogued as COSV53921610; called by muse, mutect2, varscan2
- PEX6 | c.1123C>T p.L375= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs759834813, COSV55104970; called by muse, mutect2, varscan2
- PIGW | c.1077A>G p.V359= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- POTEE | c.495C>T p.D165= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as rs779199454, COSV58224170; called by muse, mutect2, varscan2
- PPP1R3A | c.1668A>G p.G556= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV52890947; called by muse, mutect2, varscan2
- PRAMEF1 | c.102G>T p.V34= | Silent (SNP) | VAF 80/190 reads (42%) | catalogued as rs1249013526, COSV60016638; called by muse, mutect2, varscan2
- REXO1 | c.2433C>A p.G811= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs776738430, COSV50087760; called by muse, mutect2, varscan2
- RTN4 | c.999G>A p.K333= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV100463291; called by muse, mutect2
- RYR2 | c.12984A>G p.A4328= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV63707359; called by muse, mutect2
- SLC2A7 | c.1434C>T p.N478= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as rs1241220692, COSV101280791; called by muse, mutect2
- SLC35F5 | c.687G>C p.L229= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV55520117; called by muse, mutect2
- SORCS1 | c.441G>A p.P147= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs1054401425, COSV53864069, COSV53896753, COSV99547254; called by muse, mutect2, varscan2
- ST6GAL2 | c.1194T>C p.R398= | Silent (SNP) | VAF 7/193 reads (4%) | catalogued as COSV100699619; called by muse, mutect2
- TIFAB | c.270G>A p.T90= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs369906542; called by muse, mutect2, varscan2
- TMEM169 | c.615G>A p.S205= | Silent (SNP) | VAF 53/165 reads (32%) | catalogued as rs182905932; called by muse, mutect2, varscan2
- TMEM192 | c.382T>C p.L128= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV60585971, COSV60586524; called by muse, mutect2, varscan2
- TMEM219 | c.594G>T p.L198= | Silent (SNP) | VAF 21/151 reads (14%) | catalogued as COSV54239958; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.348G>A p.A116= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs140282835; called by muse, mutect2, varscan2
- TPTE | c.774T>G p.S258= (on ENST00000618007 / NM_199261.4; = p.S240= on NM_199259.4) | Silent (SNP) | VAF 26/196 reads (13%) | called by muse, varscan2
- TRPS1 | c.2307G>A p.K769= (on ENST00000220888 / NM_001330599.2; = p.K782= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/460 reads (10%) | catalogued as COSV55257252; called by muse, mutect2
- USP6NL | c.1587C>T p.N529= | Silent (SNP) | VAF 44/165 reads (27%) | catalogued as rs970209029, COSV53214667; called by muse, mutect2, varscan2
- ZFAND2A | c.135G>A p.P45= | Silent (SNP) | VAF 85/232 reads (37%) | catalogued as rs542673088, COSV57180980; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1521A>G p.E507= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV57639853; called by muse, mutect2, varscan2
- KNOP1P1 | n.57A>T | RNA (SNP) | VAF 34/95 reads (36%) | called by muse, mutect2, varscan2
- MFRP | chr11:119345443 A>T | 5'Flank (SNP) | VAF 12/40 reads (30%) | catalogued as COSV64129121; called by muse, mutect2, varscan2
- NRG1 | c.502+31279T>G | Intron (SNP) | VAF 9/164 reads (5%) | catalogued as COSV99828523; called by muse, mutect2
